Gene-level copy-number profile of tumor specimen C3L-07107-01 from CPTAC case C3L-07107, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 61.4 years (22,427 days).
Specimen C3L-07107-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Antrum; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file ca3fb5b6-6ab3-410c-8532-4466379a2faf.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-07107-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,722 have no estimate.
https://portal.gdc.cancer.gov/files/f1d0e750-85d1-4a0a-93c5-1bae4580d12e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 13; copy number 1: 3,685; copy number 2: 53,515; copy number 3: 1,654; copy number 4: 34.

Homozygous deletions (total copy number 0; autosomes only): 13 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:49,359,139–49,671,549, 11 genes (within-gene range 0–2): RHOA, RHOA-IT1, TCTA, AC104452.1, AMT, NICN1, RNA5SP130, DAG1, BSN-DT, BSN, BSN-AS1.
- chr8:43,246,755–43,247,410, 2 genes: AC022616.5, AC022616.7.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 829. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
